MMRF case MMRF_1880 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/49ade113-aca0-4d2d-a783-54681fac24f9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.5 years (24,288 days); ISS stage: II; Days to last known disease status: 918 days (2.5 years); Days to last follow up: 918 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 231 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 188 days; Days to treatment end: 189 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 190 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 51.9 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 4.41 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 10 g/dL; Glucose 5.06 mmol/L.
- Day 96 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 7.73 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 6.05 mmol/L.
- Day 187: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.49 µg/mL; Lactate Dehydrogenase 7.45 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 4.51 mmol/L.
- Day 275 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.67 µg/mL; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 357 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.92 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.24 mmol/L.
- Day 455 (ECOG 0): Hemoglobin 8.37 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 534 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 9.44 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.52 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.94 mmol/L.
- Day 652 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 158 ×10⁹/L.
- Day 736 (ECOG 0): Immunoglobulin G 9.87 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 5.08 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 7.87 mmol/L.
- Day 918 (ECOG 0): Hemoglobin 7.44 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 115 ×10⁹/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 165 cm.

Biospecimens (3 samples)
- Sample MMRF_1880_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1880_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1880_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 96 days.
